Gene-level copy-number profile of tumor specimen HCM-BROD-1124-C16-06A from HCMI case HCM-BROD-1124-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 62.6 years (22,882 days).
Specimen HCM-BROD-1124-C16-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 933bc68e-e02b-416a-99bf-a67467ecdfd8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-1124-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/dee73992-6a28-4234-aad3-d7dad339c530

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 647; copy number 1: 13,003; copy number 2: 33,060; copy number 3: 7,149; copy number 4: 4,378; copy number 5: 272; copy number 6: 298; copy number 7: 56; copy number 8: 9; copy number 10: 5; copy number 22: 9; copy number 30: 14.

Homozygous deletions (total copy number 0; autosomes only): 132 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:26,172,059–26,246,996, 17 genes: H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6, H4C7.
- chr9:20,341,669–26,644,595, 86 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:41,292,887–41,573,606, 6 genes: MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70.
- chr9:64,462,819–64,889,063, 15 genes: CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr12:12,326,056–12,357,067, 3 genes: MANSC1, RPL23AP66, LOH12CR2.
- chr22:36,281,280–36,421,644, 5 genes (within-gene range 0–1): MYH9, MIR6819, Z82215.1, FO393418.1, RPS15AP38.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 663 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:43,645,036–44,234,142, 18 genes, copy number 5: RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1.
- chr7:38,239,580–38,335,514, 14 genes, copy number 6–10 (within-gene range 6–15): TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr7:142,645,961–142,793,368, 24 genes, copy number 5–6 (within-gene range 4–6): TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr7:142,801,041–142,802,748, 1 gene, copy number 6: TRBC2.
- chr12:23,529,504–24,562,544, 1 gene, copy number 8 (within-gene range 1–8): SOX5.
- chr12:24,212,421–25,779,569, 31 genes, copy number 8–30: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262.
- chr14:22,105,343–22,497,718, 55 genes, copy number 7: TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41.
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.
- chr16:6,873,899–18,379,410, 267 genes, copy number 6 (broad region; genes not listed).
- chr20:55,504,906–64,327,972, 251 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,662. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
